Surgical pathology report (de-identified scan), TCGA case TCGA-DB-A4XG, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DB-A4XG-01A (Primary Tumor).

[page 1 of 2]
Procedure
Received
Report S.

Final Diagnosis:

A. Brain, right frontal mass, biopsy: Anaplastic oligodendroglioma (WHO grade III), see comment.

Seen in consultation with

Comment: The tumor is clinically recurrent and in progression from a WHO grade II glioma 1p19q codeleted diagnosed

IDH1(R132H) stain will be obtained and findings will be reported as an addendum.

ADDENDA:

The neoplastic cells are negative for IDH1 (R132H) immunostain.

1CD-0-3

Oligo dendroglioma, anaplastic

9451/3

Site: brain, frontal lobe C71.1

hw

10/23/12

[page 2 of 2]
Preliminary Frozen Section Consultation:

A. Brain, right frontal mass, biopsy: Oligodendroglioma. Hold to confirm and to grade on permanent sections.

Frozen section histologic interpretation performed by:

Gross Description:

A. Received fresh labeled "right frontal mass" is an 8.5 x 4.3 x 2.7 cm portion of brain. Representative sections are submitted. Grossed by

Block Summary:

Part A: Right frontal mass

- 1 Right frontal mass-1
- 2 Right frontal mass-2
- 3 Right frontal mass-3
- 4 Right frontal mass-4
- 5 Right frontal mass-5
- 6 Right frontal mass-6
- 7 Right frontal mass-7
- 8 Right frontal mass 8
- 9 Right frontal mass 9
- 10 Right frontal mass 10

END OF REPORT

Page 2 of 2

ILPAA Discrepancy		☒
Dual/Synchronous Primary	Noted	

Source: NCI Genomic Data Commons file 393aa20e-4c0f-4fc0-99a5-0f68181349f1 (TCGA-DB-A4XG.A0776539-C1FE-4798-9F65-F807B3414E7C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).